Somatic mutation profile of tumor specimen C3N-00520-01 (aliquot CPT0115000007) from CPTAC case C3N-00520, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 58.8 years (21,463 days).
Specimen C3N-00520-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aee99230-1504-418b-a811-5088a5e3251b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00520-31 (Blood Derived Normal), aliquot CPT0116000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d71d8728-0c8f-4ecc-8054-0ca406c0635c

The open-access MAF lists 44 somatic variants for this specimen: 25 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 15, Intron 3, Splice Region 2, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 104/376 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- DOCK9 | c.4062-7G>A | Splice Region (SNP) | VAF 67/249 reads (27%) | catalogued as rs769177597, COSV59635763; called by muse, mutect2, varscan2
- EPHB1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 84/345 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs542190087, COSV101213019; called by muse, varscan2
- FLG | c.3673C>A p.Q1225K | Missense Mutation (SNP) | VAF 54/906 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs757715973, CD087913; called by muse, mutect2
- GCG | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.234); catalogued as rs267598945, COSV64961354; called by muse, mutect2, varscan2
- JPH3 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as rs1319549514; called by muse, mutect2, varscan2
- LCE2C | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 32/694 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs768082821, COSV100909378; called by muse, mutect2
- PIWIL1 | c.1189C>G p.R397G | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV55350193; called by muse, mutect2, varscan2
- PTEN | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 66/273 reads (24%) | catalogued as CM110118, COSV64290316, COSV64291916, COSV64310910; called by muse, mutect2, varscan2
- SORCS3 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs752220438; called by muse, mutect2, varscan2
- TJP1 | c.3256A>G p.M1086V | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs745719967; called by muse, mutect2, varscan2
- CCDC73 | c.1677T>A p.D559E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CUEDC1 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DSG2 | c.2498T>A p.F833Y | Missense Mutation (SNP) | VAF 106/437 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCD2 | c.3164A>G p.Y1055C | Missense Mutation (SNP) | VAF 92/461 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- GLRB | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GSTM5 | c.567+7C>A | Splice Region (SNP) | VAF 31/579 reads (5%) | called by muse, mutect2
- INTS6L | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1S1 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PIK3C2B | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 67/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTEN | c.69_79del p.D24Yfs*16 | Frame Shift Del (DEL) | VAF 64/356 reads (18%) | called by mutect2, pindel, varscan2
- ROBO4 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.137); called by muse, mutect2
- SNPH | c.995T>G p.V332G | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM115 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- YPEL1 | c.71del p.I24Tfs*32 | Frame Shift Del (DEL) | VAF 97/415 reads (23%) | called by mutect2, pindel, varscan2
- BUB1 | c.525A>G p.K175= | Silent (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- CD209 | c.225C>T p.D75= | Silent (SNP) | VAF 84/425 reads (20%) | catalogued as rs375511440; called by muse, mutect2, varscan2
- FAM135B | c.2871C>T p.S957= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs757748275, COSV52720425; called by muse, mutect2, varscan2
- KLB | c.1834C>T p.L612= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs748826509; called by muse, mutect2, varscan2
- NUSAP1 | c.1134A>G p.K378= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs942063795; called by muse, mutect2, varscan2
- NWD2 | c.2535A>G p.G845= | Silent (SNP) | VAF 55/196 reads (28%) | called by muse, mutect2, varscan2
- OR5R1 | c.303G>T p.L101= | Silent (SNP) | VAF 73/264 reads (28%) | catalogued as COSV56573614; called by muse, mutect2, varscan2
- PCDHAC2 | c.1602C>G p.V534= | Silent (SNP) | VAF 44/254 reads (17%) | called by muse, mutect2, varscan2
- PPDPFL | c.117C>T p.D39= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs377716224, COSV57460806; called by muse, mutect2, varscan2
- PTCH1 | c.2034C>T p.T678= | Silent (SNP) | VAF 169/617 reads (27%) | catalogued as rs779883480; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A48 | c.168C>T p.F56= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs755946082, COSV50848839; called by muse, mutect2, varscan2
- SMAD4 | c.255T>G p.A85= | Silent (SNP) | VAF 70/326 reads (21%) | catalogued as rs1555685152; ClinVar: likely benign; called by muse, mutect2, varscan2
- TLE2 | c.960C>T p.A320= | Silent (SNP) | VAF 48/233 reads (21%) | catalogued as rs962318943; called by muse, mutect2, varscan2
- WDFY4 | c.8577G>C p.T2859= | Silent (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- ZBED1 | c.1071G>T p.T357= | Silent (SNP) | VAF 101/491 reads (21%) | called by muse, mutect2, varscan2
- CHRM2 | c.-47+33704T>C | Intron (SNP) | VAF 209/467 reads (45%) | catalogued as rs768999505; called by muse, mutect2, varscan2
- HNRNPK | c.1093-24_1093-19del | Intron (DEL) | VAF 23/127 reads (18%) | called by mutect2, pindel, varscan2
- LINC02448 | n.343G>T | RNA (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- NEB | c.8890-2857A>T | Intron (SNP) | VAF 34/126 reads (27%) | called by muse, varscan2
